Surgical pathology report (de-identified scan), TCGA case TCGA-L4-A4E6, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Gundersen Lutheran Health System, specimen TCGA-L4-A4E6-01A (Primary Tumor).

[page 1 of 3]
Patient:

Med. Record No.:

Date of Birth:

Submitted by:

Report also to

Age:

Sex:

M

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

DIAGNOSIS:

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: lung, upper lobe C34.1
w 9/27/12

SPECIMEN

Specimen type: Wedge excision (Part A) and right upper lobectomy (Part B)

Tumor site: Right upper lobe

Additional tumor location info: Subpleura

TUMOR

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated (G3 of 4)

Tumor size: 2cm

Tumor focality: Unifocal

Direct extension of tumor: No invasion of visceral pleura or adjacent structures

Tumor-associated atelectasis/obstructive pneumonitis: Absent

Lymphovascular space invasion: Venous invasion

Additional findings: None

MARGINS

All margins negative for carcinoma

Distance to nearest margin: 4.5cm

Nearest margin: Bronchial margin

LYMPH NODES

All sampled lymph nodes are benign

Number of nodes evaluated: 6

STAGING (AJCC)

Primary Tumor: pT1

Lymph Nodes: pN0

[page 2 of 3]
Patient: [REDACTED]

CLINICAL INFORMATION:

Right upper lobe lung mass.

SPECIMEN(S) RECEIVED:

- A. Right upper lobe mass
- B. Additional right upper lobe for margins

GROSS DESCRIPTION:

A. Received fresh is a 10.5 x 5.5 x 3.5 cm wedge resection of lung. A staple line indicates the resection margin. The pleural surface, smooth and pale tan-red, shows minimal anthracotic stippling. Located approximately 2 cm from the staple line is a 1.0 x 0.8 cm area of pleural puckering. Beneath the pleura is an ill-circumscribed mass measuring approximately 2.0 x 1.8 x 1.2 cm. The periphery of the mass is firm and gray, and the center is cavitated. No additional masses are identified throughout the remaining parenchyma. Intraoperative touch preparations are prepared. A small portion of the mass, as well as normal lung, is obtained for the

Three sections of the mass with overlying pleura (inked black) are submitted in A1-A3.

INTRAOPERATIVE TOUCH PREP DIAGNOSIS: Non-small cell carcinoma.

B. Received fresh is a 106 gram, 17 x 8.0 x 5.4 cm lobe of lung. The pleura exhibits minimal to moderate anthracotic stippling. Towards the center of the resection is a 9.0 x 5.5 cm defect in the pleura, representing the prior wedge resection. The edges of the pleural defect are 1.5 cm or greater from the staple line. Sections of the lung reveal a spongy tan-red parenchyma with no additional masses. Near the bronchial margin (which is 2.5 cm or greater from the staple line) are several small anthracotic lymph nodes. The bronchial margin is submitted for frozen section in B1, representative sections of lung parenchyma in B2 and B3, and lymph nodes in B4.

FROZEN SECTION DIAGNOSIS: Bronchial margin negative for malignancy. Reported to [REDACTED]

Immunohistochemistry Results

Formalin-fixed, paraffin-embedded tissue is utilized. Tissue sections are incubated with the following antibodies. Positive and negative controls stain appropriately. Complete procedural methodology is available upon request. Results indicated below:

Material: Block A1

Marker For:	Result	Comment
TTF-1	Positive	
p63	Negative	

Note: The performance characteristics of all immunohistochemical stains cited in this report were determined by the Department of Pathology at [REDACTED] as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88). Some of these tests may rely on the use of "analyte specific reagents" and have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to this report. These tests are used for clinical purposes, and should not be regarded as investigational or for research.
The immunohistochemistry laboratory at [REDACTED] Department of Pathology is certified by the Centers for Medicare and Medicaid Services (formerly HCFA) as a high complexity laboratory under CLIA '88

Slides were microscopically examined by the pathologist.

[page 3 of 3]
Patient: [REDACTED]

[REDACTED]

[REDACTED]

Evaluation performed by
[REDACTED]
Electronically signed

Source: NCI Genomic Data Commons file d2c52b80-e904-4bd8-9c49-68b6457399d4 (TCGA-L4-A4E6.A6FC7AD1-BE0E-4B6C-A71C-CBDC7CD58968.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).